Somatic mutation profile of tumor specimen BA3119D (aliquot aq-BA3119D) from BEATAML1.0 case 2778, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,369 days).
Specimen BA3119D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d674feab-96c2-4ec1-a7c1-d2bada2558d9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3147D (Solid Tissue Normal), aliquot aq-BA3147D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26983c2e-035f-4243-b075-bfce3a48e6f6

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC12A7 | c.1507T>C p.S503P | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1378683915; called by muse, mutect2
